Somatic mutation profile of tumor specimen TARGET-50-PAJLNJ-01A (aliquot TARGET-50-PAJLNJ-01A-01D) from TARGET case TARGET-50-PAJLNJ, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: female; Vital status: Dead; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 0.9 years (325 days).
Specimen TARGET-50-PAJLNJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 208a5cdf-30c4-43c2-9446-c69add56c71a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PAJLNJ-11A (Solid Tissue Normal), aliquot TARGET-50-PAJLNJ-11A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d0199f5-b267-48cc-b108-51a8933c0bf0

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 2, In Frame Del 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4669_4670del p.I1557* | Frame Shift Del (DEL) | VAF 54/286 reads (19%) | catalogued as rs786201118; ClinVar: pathogenic; called by mutect2, varscan2
- CTNNB1 | c.133_135del p.S45del | In Frame Del (DEL) | VAF 59/138 reads (43%) | hotspot (GDC flag); catalogued as rs587776850; ClinVar: pathogenic / other; called by mutect2, pindel, varscan2
- RNF208 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 58/112 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs374122763; called by muse, varscan2
- WT1 | c.748A>T p.K250* | Nonsense Mutation (SNP) | VAF 60/61 reads (98%) | catalogued as COSV60072139; called by muse, mutect2, varscan2
- TENM1 | c.5239G>C p.G1747R | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- DRP2 | c.2145C>T p.A715= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as rs1015769278; called by muse, mutect2, varscan2
- SPATA31E1 | c.3234G>A p.A1078= | Silent (SNP) | VAF 46/107 reads (43%) | catalogued as rs762165544; called by muse, mutect2, varscan2
